Gene-level copy-number profile of specimen HCM-BROD-0830-C71-85R from HCMI case HCM-BROD-0830-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.4 years (21,323 days).
Specimen HCM-BROD-0830-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4a26382e-b1a9-4192-b93c-6220f29184e7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0830-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/612f1c11-062b-4444-b575-39ce3cc7dcce

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 109; copy number 2: 11,964; copy number 3: 31,070; copy number 4: 12,562; copy number 5: 2,593; copy number 6: 9; copy number 7: 1; copy number 8: 1; copy number 9: 5; copy number 10: 14; copy number 21: 67.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 88 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:54,009,789–54,064,605, 2 genes, copy number 9 (within-gene range 3–9): CHIC2, AC110792.2.
- chr4:54,229,280–54,376,752, 3 genes, copy number 9 (within-gene range 3–9): PDGFRA, LINC02283, AC098587.1.
- chr6:32,517,353–32,530,287, 1 gene, copy number 7: HLA-DRB5.
- chr7:54,419,444–55,260,256, 14 genes, copy number 10: SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr7:116,672,196–122,062,036, 67 genes, copy number 21 (broad region; genes not listed).
- chr21:44,158,740–44,160,076, 1 gene, copy number 8: LINC01678.

Autosomal genes at a single copy (total copy number 1): 109. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
